Gene-level copy-number profile of tumor specimen TARGET-40-PAKZZK-01A from TARGET case TARGET-40-PAKZZK, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.3 years (4,864 days).
Specimen TARGET-40-PAKZZK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.5c309186-8fe2-5406-8270-2a2fa6f42129.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAKZZK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 410 have no estimate.
https://portal.gdc.cancer.gov/files/a3e05988-908e-42de-88d8-fc4be6efb698

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,506; copy number 1: 890; copy number 2: 23,343; copy number 3: 16,735; copy number 4: 6,802; copy number 5: 5,402; copy number 6: 1,777; copy number 7: 1,232; copy number 8: 1,580; copy number 9: 173; copy number 10: 424; copy number 11: 192; copy number 12: 5; copy number 13: 90; copy number 14: 32; copy number 16: 25; copy number 17: 3; copy number 41: 2.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,709,235–117,027,039, 7 genes: TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr7:78,486,530–78,487,028, 1 gene: AC007237.1.
- chr11:80,321,620–80,327,911, 1 gene: AP006295.1.
- chr13:48,232,612–48,303,661, 2 genes: ITM2B, RB1-DT.
- chr13:48,316,863–48,444,704, 5 genes (within-gene range 0–2): PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,872 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–78,750,659, 2,089 genes, copy number 5–11 (broad region; genes not listed).
- chr1:143,541,768–173,669,851, 1,086 genes, copy number 6–9 (broad region; genes not listed).
- chr1:175,877,343–176,845,601, 15 genes, copy number 5 (within-gene range 2–5): LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7, PAPPA2, PTP4A1P7.
- chr1:182,839,347–182,982,318, 7 genes, copy number 7–8 (within-gene range 3–8): DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P.
- chr2:24,789,734–56,386,172, 548 genes, copy number 5 (within-gene range 5–10) (broad region; genes not listed).
- chr2:88,857,161–124,915,287, 708 genes, copy number 7–10 (within-gene range 2–15) (broad region; genes not listed).
- chr3:103,159,960–104,503,266, 7 genes, copy number 6: RNU1-43P, NDUFA4P2, MIR548AB, AC046144.1, TUBBP11, RAP1BP2, AC091804.1.
- chr3:196,739,857–198,222,513, 49 genes, copy number 6: PAK2, RNU4-89P, RNU6-42P, SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ, AC011322.1, RPSAP69, MELTF, MELTF-AS1, DLG1, MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr4:49,203,171–58,118,070, 146 genes, copy number 5–6 (broad region; genes not listed).
- chr4:164,597,719–173,169,652, 105 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:58,198–25,445,925, 411 genes, copy number 7–8 (broad region; genes not listed).
- chr5:50,396,192–53,094,779, 36 genes, copy number 7–8 (within-gene range 3–8): EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3.
- chr6:3,585,101–4,135,597, 20 genes, copy number 6 (within-gene range 3–6): AL033523.1, AL033523.2, PXDC1, AL391422.4, AL391422.1, AL391422.3, AL391422.2, FAM50B, AL590004.3, AL590004.2, AL590004.1, TDGF1P4, GLRX3P2, AL138831.3, AL138831.2, AL138831.1, PRPF4B, FAM217A, C6orf201, ECI2.
- chr6:166,058,505–169,738,992, 94 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr7:70,972–35,186,041, 610 genes, copy number 5–14 (within-gene range 3–14) (broad region; genes not listed).
- chr7:44,577,894–54,812,727, 142 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:100,177,563–102,456,825, 101 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 6–17 (broad region; genes not listed).
- chr9:36,190,856–41,701,096, 154 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:80,527,960–85,627,922, 47 genes, copy number 5 (within-gene range 1–5): RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2, DLG2, DLG2-AS2, AP002370.1, LDHAL6DP.
- chr11:84,887,207–122,027,667, 742 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr13:70,459,464–71,914,178, 10 genes, copy number 5: RNU6-54P, AL445264.1, MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21.
- chr13:86,725,500–87,674,235, 8 genes, copy number 6 (within-gene range 4–6): TXNL1P1, LINC00430, UBBP5, LIN28AP2, AL360267.2, AL360267.1, MIR4500HG, AL355578.1.
- chr15:97,215,812–101,933,350, 120 genes, copy number 5–7 (broad region; genes not listed).
- chr17:8,199,123–10,730,023, 72 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:13,494,032–18,414,380, 189 genes, copy number 7–14 (broad region; genes not listed).
- chr17:18,537,800–19,633,825, 76 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr17:21,075,362–27,170,310, 63 genes, copy number 6 (broad region; genes not listed).
- chr17:71,829,870–83,095,122, 456 genes, copy number 5 (broad region; genes not listed).
- chr18:13,183,402–15,330,282, 77 genes, copy number 5 (broad region; genes not listed).
- chr18:61,333,430–66,069,647, 61 genes, copy number 5 (broad region; genes not listed).
- chr19:11,814,273–16,104,254, 255 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:27,638,483–27,984,984, 14 genes, copy number 5: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1.
- chr19:29,002,319–31,427,302, 42 genes, copy number 5 (within-gene range 3–5): LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1.
- chr20:1,113,240–2,641,784, 49 genes, copy number 5–41 (within-gene range 4–41): PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869, NSFL1C, SIRPB2, AL049634.1, RNU6-917P, SIRPD, AL049634.2, SIRPB1, AL049634.3, SIRPG, SIRPG-AS1, SIRPB3P, RN7SL561P, AL109809.3, AL109809.2, AL109809.4, CKAP2LP1, AL109809.1, AL117335.1, SIRPA, PDYN-AS1, PDYN, RPL7P2, STK35, AL359916.1, AL121899.3, AL121899.4, AL121899.1, AL121899.2, TGM3, TGM6, Y_RNA, SNRPB, AL049650.1, ZNF343, TMC2.
- chr20:4,059,633–12,318,221, 129 genes, copy number 5–7 (broad region; genes not listed).
- chr20:23,179,272–23,990,454, 37 genes, copy number 5 (within-gene range 4–5): AL118508.1, AL390037.1, NXT1-AS1, NXT1, LINC01431, GZF1, NAPB, RNA5SP479, CSTL1, CST11, AL096677.1, Y_RNA, CST12P, AL109954.1, AL109954.2, CST8, CST13P, CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4, CST2P1, AL591074.2, CST1, CSTP2, AL591074.1, CST2, CST5, CSTP1, AL133466.1, GGTLC1, POM121L3P.
- chr21:15,928,296–38,977,774, 412 genes, copy number 5–16 (broad region; genes not listed).
- chr21:39,127,568–41,767,089, 56 genes, copy number 5–7: RPL23AP12, PCBP2P1, AF129408.2, PSMG1, BRWD1, AF129408.1, TIMM9P2, BRWD1-IT1, METTL21AP1, BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA, RNF6P1, GET1, GET1-SH3BGR, LCA5L, SH3BGR, MIR6508, MYL6P2, RPS26P4, JCADP1, B3GALT5, B3GALT5-AS1, AF064860.1, AF064860.2, IGSF5, PCP4, DSCAM, MIR4760, DSCAM-AS1, AF064863.1, DSCAM-IT1, AF064866.1, YRDCP3, AL773573.1, LINC00323, MIR3197, BACE2, PLAC4, BACE2-IT1, FAM3B, MX2, MX1, AP001610.2, TMPRSS2, AP001610.1, AP001610.3, AP006748.1, PCSEAT, LINC00111, LINC00479, LINC00112, RIPK4, AP001615.1, MIR6814.
- chr21:45,073,853–46,665,124, 55 genes, copy number 5–6 (within-gene range 2–6): ADARB1, AL133499.1, LINC00334, POFUT2, LINC00205, BX322557.2, LINC00315, BX322557.1, LINC00316, MTCO1P3, BX322559.1, BX322562.1, COL18A1, COL18A1-AS2, COL18A1-AS1, MIR6815, SLC19A1, LINC01694, AL133493.1, AL133493.2, PCBP3, AL133492.1, PCBP3-AS1, AJ011931.2, AJ011931.1, AJ239328.1, AJ011932.1, COL6A1, AP001476.1, AP001476.3, AP001476.2, PSMA6P3, AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1.

Autosomal genes at a single copy (total copy number 1): 495. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
